Somatic mutation profile of tumor specimen TCGA-L5-A4OW-01A (aliquot TCGA-L5-A4OW-01A-11D-A28B-09) from TCGA case TCGA-L5-A4OW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 56.9 years (20,796 days).
Specimen TCGA-L5-A4OW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c1a61e2-19cf-448b-b650-9391538bb193.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OW-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OW-11A-11D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6a66241-e611-4f89-8b4f-729c4a68fc62

The open-access MAF lists 247 somatic variants for this specimen: 186 protein-altering or splice-affecting, 55 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 55, Nonsense Mutation 7, Frame Shift Del 3, RNA 3, Splice Region 2, Frame Shift Ins 2, Intron 2, 3'UTR 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DKC1 | c.1193T>C p.L398P | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199422253, CM1512416; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | hotspot (GDC flag); catalogued as rs1555526097, CM942118, COSV52735517, COSV53025177, COSV53136193, COSV53312374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1306T>G p.L436V (on ENST00000272895 / NM_173076.3; = p.L118V on NM_015657.3) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV55951686; called by mutect2, varscan2
- ABCC8 | c.4435G>A p.E1479K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV56850846; called by muse, mutect2
- ADAMDEC1 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV56474020; called by muse, mutect2
- ADAMTS16 | c.1939T>G p.F647V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs1263265207, COSV57006323, COSV99939817; called by muse, mutect2, varscan2
- AK7 | c.376A>C p.M126L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV50885364; called by muse, mutect2, varscan2
- ALDH8A1 | c.1377dup p.M460Dfs*8 | Frame Shift Ins (INS) | VAF 6/55 reads (11%) | catalogued as rs1423245247; called by mutect2, pindel
- ATP10A | c.2881T>G p.S961A | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as rs200374453, COSV100791520; called by muse, mutect2, varscan2
- ATP10B | c.3253G>A p.D1085N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs528980708; called by muse, mutect2
- CAPN12 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs565486508, COSV61015027; called by muse, mutect2, varscan2
- CNTN1 | c.1514C>T p.T505M | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs556601462, COSV61638909; called by muse, mutect2, varscan2
- CPS1 | c.3185A>C p.N1062T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CD064534; called by muse, mutect2, varscan2
- CPS1 | c.4415T>G p.L1472R | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs756635859, COSV51802426; called by muse, mutect2, varscan2
- CSMD1 | c.658T>G p.S220A | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV68235011; called by muse, mutect2, varscan2
- CYLC1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.135); catalogued as COSV100254393, COSV61413056; called by muse, mutect2
- DISP3 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.493); catalogued as COSV53829806; called by muse, mutect2, varscan2
- DLGAP2 | c.1199A>C p.K400T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.648); catalogued as rs1490637466; called by muse, mutect2
- DNAH5 | c.12599A>G p.K4200R | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54201514, COSV54202045, COSV54212456; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.303); catalogued as rs778973141, COSV57515633; called by muse, mutect2
- FBN3 | c.5416C>T p.R1806W | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs370586224, COSV54463678; called by muse, mutect2, varscan2
- FLVCR2 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV53163957; called by muse, mutect2, varscan2
- FMR1NB | c.520T>C p.F174L | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV63272860; called by muse, mutect2, varscan2
- GRID2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV99940993; called by muse, mutect2, varscan2
- GSDMC | c.1195C>G p.L399V | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99415410; called by muse, mutect2, varscan2
- H2BC17 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as rs1271200725; called by muse, mutect2
- HBB | c.268A>G p.S90G | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as CM099719; called by muse, mutect2, varscan2
- HEPH | c.1244A>C p.K415T (on ENST00000343002; = p.K148T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV57966063; called by muse, mutect2, varscan2
- HERC1 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs748144670; called by muse, mutect2, varscan2
- IFI44 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66074539; called by muse, mutect2, varscan2
- IGLL1 | c.286C>A p.H96N | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV50770206; called by muse, mutect2
- IRAK1 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs373743090; called by muse, mutect2, varscan2
- KAT5 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753132884, COSV100383916, COSV100384084; called by muse, mutect2, varscan2
- KAT6A | c.2779C>T p.P927S | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs1207270525; called by muse, mutect2
- KCNA5 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV52905647; called by muse, mutect2, varscan2
- KCNC3 | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298855464; called by muse, mutect2
- KLK4 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs970897746, COSV60675970; called by muse, mutect2, varscan2
- LAMA1 | c.7459C>T p.R2487W | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs372517307; called by muse, mutect2, varscan2
- LINGO3 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs1435533314, COSV68261951; called by muse, mutect2, varscan2
- LRRC7 | c.752G>T p.W251L (on ENST00000651989 / NM_001370785.2; = p.W218L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV50554071; called by muse, mutect2, varscan2
- LTBP1 | c.4876G>A p.G1626S (on ENST00000404816 / NM_206943.4; = p.G1300S on NM_000627.4) | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1167783323, COSV55384822, COSV55386094; called by muse, mutect2, varscan2
- MAF1 | c.83+1G>A p.X28_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | catalogued as rs1009787693; called by muse, mutect2, varscan2
- MAGED1 | c.2293T>G p.F765V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV58516176; called by muse, mutect2, varscan2
- MAN2B2 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs781115808, COSV53450542; called by muse, mutect2, varscan2
- MBTPS2 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63411420; called by muse, mutect2, varscan2
- MTMR3 | c.2524G>A p.V842M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs199966820; called by muse, mutect2, varscan2
- NETO2 | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs772817589, COSV57452814; called by muse, mutect2, varscan2
- NPY2R | c.914T>G p.L305R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61529608; called by muse, mutect2, varscan2
- OR4N2 | c.125A>C p.N42T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60050049; called by muse, mutect2, varscan2
- OR8G1 | c.310T>C p.F104L | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as rs1226243999; called by muse, mutect2, varscan2
- PCDHA10 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56532848; called by muse, mutect2, varscan2
- PCDHB3 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV50564230; called by muse, mutect2, varscan2
- PCDHGB6 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1458873114, COSV53966653, COSV99538995; called by muse, mutect2
- PDGFRB | c.1853C>T p.T618M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139554380, COSV55807667; called by muse, mutect2, varscan2
- PDHA2 | c.124T>G p.Y42D | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV99756476; called by muse, mutect2, varscan2
- PIK3CA | c.2726T>G p.F909C | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55891776; called by muse, mutect2, varscan2
- PKD1L2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs201124846, COSV61411197, COSV61413750; called by muse, mutect2
- PLCG1 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs756135063; called by muse, mutect2, varscan2
- PNMA8B | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs538950722, COSV66537906; called by muse, mutect2, varscan2
- PRSS1 | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1407084355; called by muse, mutect2
- PXDNL | c.3226G>A p.E1076K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs771432328, COSV62496490; called by muse, mutect2, varscan2
- RECQL4 | c.1765G>A p.G589S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs1060501364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RELA | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58015334; called by muse, mutect2, varscan2
- RP1L1 | c.5497G>A p.E1833K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs1443701668, COSV66761230; called by muse, mutect2
- RPS10-NUDT3 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.972); catalogued as rs774624551; called by muse, mutect2, varscan2
- RYR2 | c.9407G>A p.S3136N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs748194372; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD9 | c.873A>C p.E291D | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV66073876; called by muse, mutect2
- SCN4A | c.5492T>A p.V1831D | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.641); catalogued as rs1300925199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCUBE1 | c.2486C>T p.A829V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1320417672, COSV62610018; called by muse, mutect2, varscan2
- SEC13 | c.271G>A p.G91S (on ENST00000350697 / NM_183352.3; = p.G94S on NM_030673.4) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs137884718; called by muse, mutect2, varscan2
- SERPINB2 | c.553T>G p.L185V | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55091234; called by muse, mutect2
- SFTPA1 | c.596G>C p.R199P | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.613); catalogued as COSV100957220; called by muse, mutect2, varscan2
- SLC45A1 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs772289747, COSV99239167, COSV99239646; called by muse, mutect2, varscan2
- SPACA1 | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV52760224; called by muse, mutect2, varscan2
- SSX2IP | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs373832172; called by muse, varscan2
- STIP1 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs1434290633; called by muse, mutect2, varscan2
- SUCNR1 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV62912640; called by muse, mutect2, varscan2
- SULF1 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs376825615, COSV52675587; called by muse, mutect2, varscan2
- TAFA1 | c.164A>G p.K55R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.802); catalogued as COSV72041521; called by muse, mutect2, varscan2
- TGM5 | c.752A>G p.N251S (on ENST00000220420 / NM_201631.4; = p.N169S on NM_004245.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV55008614; called by muse, mutect2, varscan2
- TLN2 | c.5962G>A p.G1988R | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60885874, COSV60895777; called by muse, mutect2
- TMED6 | c.175T>A p.F59I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV54749560; called by muse, mutect2, varscan2
- TMEM131L | c.2272G>C p.D758H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as COSV99546714; called by muse, mutect2
- TMEM184C | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as COSV99031061; called by muse, mutect2
- TMEM94 | c.3602G>A p.R1201H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs996997278; called by muse, mutect2, varscan2
- TRIML2 | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as rs1404806612; called by muse, mutect2, varscan2
- TRPS1 | c.2675C>A p.S892Y (on ENST00000220888 / NM_001330599.2; = p.S905Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55228167; called by muse, mutect2, varscan2
- TRPV3 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs1229524183; called by muse, mutect2
- TRPV4 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55680261, COSV55681496; called by muse, mutect2, varscan2
- TTN | c.57040G>A p.E19014K (on ENST00000591111; = p.E11590K on NM_003319.4) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | PolyPhen probably damaging (0.994); catalogued as rs776314797, COSV59983239; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.16142A>G p.K5381R (on ENST00000591111; = p.K4454R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | PolyPhen benign (0.003); catalogued as COSV100606891, COSV60182756; called by muse, mutect2, varscan2
- USP6 | c.3245G>A p.R1082Q | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1175283983, COSV51502067; called by muse, mutect2, varscan2
- ZNF408 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as rs761309547, COSV61237871; called by muse, mutect2, varscan2
- ACSM2A | c.1191T>A p.D397E (on ENST00000219054; = p.D318E on NM_001308169.2) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS12 | c.4575A>C p.K1525N | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTS3 | c.1328G>A p.G443D | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ADGRF3 | c.2334G>T p.L778F (on ENST00000311519 / NM_001145168.1; = p.L579F on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP10A | c.2144T>C p.V715A | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- BICC1 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BMP3 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BPTF | c.7540C>T p.Q2514* | Nonsense Mutation (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- CACNA2D3 | c.1380T>C p.T460= | Splice Region (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- CCDC158 | c.1848del p.D617Mfs*11 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- CCDC86 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- CGB8 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.482); called by mutect2, varscan2
- CHST7 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CNGB3 | c.100A>C p.S34R | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CR1 | c.3867G>T p.G1289= | Splice Region (SNP) | VAF 28/186 reads (15%) | called by muse, mutect2, varscan2
- CSMD3 | c.10518T>G p.N3506K (on ENST00000297405 / NM_001363185.1; = p.N3337K on NM_052900.3) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CSTF1 | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DBT | c.770A>C p.K257T | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DRD3 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.741); called by muse, mutect2
- DSEL | c.2520A>C p.K840N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- EDA2R | c.322A>T p.T108S | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.124); called by muse, mutect2
- EPHX3 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2
- ESS2 | c.1319G>A p.S440N | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2
- FARP1 | c.1399C>G p.P467A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- FAT4 | c.3071A>G p.D1024G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAT4 | c.14019T>G p.S4673R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- FMNL2 | c.1949A>T p.E650V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- FOLH1 | c.631G>T p.G211* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- FZD1 | c.1798T>G p.F600V | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GALNT9 | c.1478G>C p.C493S (on ENST00000328957 / NM_001122636.2; = p.C127S on NM_021808.3) | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GHDC | c.938T>G p.L313R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- GJA5 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- HDLBP | c.2256G>T p.K752N | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- HP1BP3 | c.1100A>T p.Y367F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- HUWE1 | c.6090A>T p.Q2030H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- IFIH1 | c.2522T>A p.I841N | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.149); called by muse, mutect2
- IL12RB2 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KIR3DL1 | c.679_680dup p.A228Qfs*14 | Frame Shift Ins (INS) | VAF 36/146 reads (25%) | called by mutect2, varscan2
- KLK4 | c.690A>C p.Q230H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- KRT14 | c.1020C>G p.N340K | Missense Mutation (SNP) | VAF 108/542 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- LETM2 | c.313C>A p.P105T (on ENST00000379957 / NM_001286819.2; = p.P58T on NM_144652.3) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.162); called by muse, mutect2
- LOXL2 | c.905T>A p.V302E | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.297); called by muse, mutect2
- LPCAT1 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 40/344 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- MAP3K1 | c.786_790del p.K263Rfs*36 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- MAP3K21 | c.1870T>A p.L624I | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MROH1 | c.4406C>T p.S1469F | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MYB | c.1857G>C p.Q619H | Missense Mutation (SNP) | VAF 443/497 reads (89%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- NEDD9 | c.2262C>A p.H754Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEXMIF | c.3125A>T p.E1042V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NLRP3 | c.1816C>A p.L606M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NNMT | c.773G>C p.R258T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- NRCAM | c.2029A>G p.I677V (on ENST00000379028 / NM_001371124.1; = p.I661V on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- OR4C15 | c.691A>C p.M231L (on ENST00000314644; = p.M177L on NM_001001920.2) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR5L2 | c.67T>G p.L23V | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR6M1 | c.451T>A p.F151I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- PCDHGA6 | c.1924C>A p.L642I | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- PDE8B | c.1202C>A p.S401Y | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- PDGFD | c.140C>A p.T47K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PHF21A | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 139/374 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- PIWIL2 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLS3 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- PPP1R42 | c.164T>C p.L55S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PPP4R1 | c.139C>A p.P47T (on ENST00000400556 / NM_001042388.3; = p.P30T on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRB3 | c.752C>T p.P251L (on ENST00000381842; = p.P293L on NM_006249.5) | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2
- PRDM13 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PROX1 | c.1673A>C p.E558A | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ROBO2 | c.761C>A p.P254Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCML2 | c.1662T>G p.Y554* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- SCN3A | c.2200G>T p.A734S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- SIGLEC5 | c.1270C>A p.L424M | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SLC39A12 | c.992A>T p.E331V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SLC8A1 | c.1056A>T p.Q352H | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SLCO3A1 | c.1058G>T p.C353F | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- SLITRK1 | c.1733G>T p.C578F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX16 | c.644A>T p.D215V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- STAG2 | c.395C>A p.T132K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- STK32B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SUMO1 | c.43del p.D15Ifs*24 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | called by mutect2, pindel, varscan2
- TCERG1L | c.1189A>C p.T397P | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TIAM1 | c.2739T>A p.D913E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM132D | c.1879G>C p.G627R | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM42 | c.1606A>G p.S536G | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- UBQLNL | c.1374G>T p.Q458H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VCAN | c.2544A>C p.E848D | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- VN1R2 | c.1037G>T p.W346L | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2
- WFIKKN1 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ZC3H4 | c.743G>T p.R248M | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ZIC1 | c.896A>G p.E299G | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF208 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF518B | c.1123G>T p.G375W | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ZNF536 | c.1688A>C p.K563T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF564 | c.1592A>T p.K531I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZNF594 | c.2089C>T p.Q697* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- APOB | c.9810C>T p.F3270= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs138010392; ClinVar: likely benign; called by muse, mutect2, varscan2
- ART5 | c.309G>A p.S103= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs779219965, COSV100731555; called by muse, mutect2, varscan2
- CD1E | c.192T>A p.T64= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100936969, COSV63772919; called by muse, mutect2
- CSMD1 | c.3972C>T p.F1324= (on ENST00000520002; = p.F1323= on NM_033225.6) | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs868718210, COSV59304465, COSV59355574; called by muse, mutect2, varscan2
- DEFB118 | c.123A>T p.G41= | Silent (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- EPN2 | c.1101C>T p.G367= | Silent (SNP) | VAF 39/71 reads (55%) | catalogued as rs1432497852; called by muse, mutect2, varscan2
- F8 | c.3393T>A p.T1131= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- FAT4 | c.11130A>C p.T3710= | Silent (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- GRID2 | c.798C>T p.N266= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs755074343, COSV56180903; called by muse, mutect2, varscan2
- HIVEP3 | c.492C>T p.F164= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs772680628, COSV56009413; called by muse, mutect2, varscan2
- HUWE1 | c.8961C>T p.N2987= | Silent (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- ITGB5 | c.2244C>T p.I748= | Silent (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- KATNBL1 | c.813A>G p.Q271= | Silent (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- KDM2A | c.1587G>A p.K529= | Silent (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- KIAA1210 | c.2802T>G p.T934= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs1313639578; called by muse, mutect2, varscan2
- KIAA1210 | c.2613A>G p.E871= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV101274492; called by muse, varscan2
- KRT14 | c.376C>T p.L126= | Silent (SNP) | VAF 336/1616 reads (21%) | catalogued as rs764842172; called by muse, mutect2, varscan2
- LAMA1 | c.8313C>A p.G2771= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV101057950, COSV67540184; called by muse, mutect2
- LRP1B | c.6507T>G p.A2169= | Silent (SNP) | VAF 16/42 reads (38%) | called by muse, varscan2
- MERTK | c.819C>T p.S273= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV99775421; called by muse, mutect2, varscan2
- MGAT5 | c.1911C>T p.A637= | Silent (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- MUC16 | c.23136C>A p.P7712= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs558504850; called by mutect2, varscan2
- NBEAL2 | c.3396G>A p.A1132= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as rs902885415; called by muse, mutect2
- NCBP1 | c.2163G>A p.L721= | Silent (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- OBSCN | c.3315G>A p.V1105= | Silent (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- OR10G9 | c.441T>G p.T147= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as COSV66686924; called by muse, mutect2, varscan2
- OR5D18 | c.579T>G p.T193= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV61738404; called by muse, mutect2, varscan2
- OR5K3 | c.501T>C p.T167= | Silent (SNP) | VAF 48/117 reads (41%) | catalogued as rs971440801; called by muse, mutect2, varscan2
- OR5T2 | c.681T>C p.S227= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV57588476, COSV57589308, COSV57590451; called by muse, mutect2, varscan2
- PCDHGA4 | c.318C>T p.F106= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV53902032; called by muse, mutect2
- PLXNB3 | c.3111C>A p.G1037= | Silent (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
- PNLIPRP3 | c.1302A>G p.A434= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs747907448, COSV100982367; called by muse, mutect2, varscan2
- PNMT | c.483G>A p.Q161= | Silent (SNP) | VAF 284/654 reads (43%) | catalogued as COSV99510641; called by muse, mutect2, varscan2
- PRL | c.264T>G p.T88= | Silent (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2
- PXDN | c.2937C>T p.N979= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99414335; called by muse, mutect2
- RAB4B | c.393C>T p.V131= | Silent (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- RAPGEF3 | c.1203G>A p.L401= (on ENST00000389212; = p.L359= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs757103677; called by muse, varscan2
- SAFB | c.525G>A p.P175= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs758696281, COSV52652537; called by muse, mutect2, varscan2
- SCUBE2 | c.792G>A p.E264= | Silent (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- SEMA6D | c.54G>A p.L18= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- SEMA6D | c.2941T>C p.L981= (on ENST00000316364 / NM_153618.2; = p.L919= on NM_020858.2) | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV60373388, COSV60376846; called by muse, mutect2, varscan2
- SLC5A1 | c.594G>A p.A198= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as rs184213779, COSV56688485, COSV99833335; called by muse, mutect2, varscan2
- SLC6A1 | c.888C>T p.Y296= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs144034291; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC9A6 | c.1267T>C p.L423= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- SLITRK2 | c.1768T>C p.L590= | Silent (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- SPPL2C | c.411G>A p.Q137= | Silent (SNP) | VAF 57/100 reads (57%) | called by muse, mutect2, varscan2
- TLE4 | c.1704C>T p.R568= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- TMEM176B | c.279G>A p.L93= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as rs774621749; called by muse, mutect2, varscan2
- TTPAL | c.954C>T p.P318= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs374289262; called by muse, mutect2, varscan2
- TUBA1B | c.1191G>A p.L397= | Silent (SNP) | VAF 30/190 reads (16%) | catalogued as COSV100254166; called by muse, mutect2, varscan2
- WIPF1 | c.1482T>G p.G494= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs771194136; called by muse, mutect2, varscan2
- XCR1 | c.873G>A p.G291= | Silent (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- ZFHX4 | c.243C>A p.P81= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- ZNF766 | c.447T>G p.L149= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- ZNF99 | c.1719T>C p.A573= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs369557719; called by muse, mutect2, varscan2
- CIDEA | c.38+395G>A | Intron (SNP) | VAF 4/70 reads (6%) | catalogued as rs1387398997; called by muse, mutect2
- LCE4A | c.*2C>A | 3'UTR (SNP) | VAF 5/82 reads (6%) | catalogued as COSV100140034; called by muse, mutect2
- MIR129-2 | n.83G>A | RNA (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2
- MIR485 | n.69_70del | RNA (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- MROH8 | c.370+2416T>G | Intron (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2
- UBTFL2 | n.661C>T | RNA (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
